Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6628, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6628-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. TERMINAL ILEUM AND RIGHT COLON

DIAGNOSIS:

- A. TERMINAL ILEUM AND RIGHT COLON, RIGHT HEMICOLECTOMY:
- MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA OF CECUM, TUMOR SIZE 4.5 x 3.2 CM, INVADING INTO SUPERFICIAL MUSCULARIS PROPRIA.
- SURGICAL RESECTION MARGINS, NEGATIVE FOR TUMOR.
- SIXTEEN (16) PERICOLIC LYMPH NODES, NEGATIVE FOR TUMOR (0/16).
- TWO (2) HYPERPLASTIC POLYPS IN COLON.
- VERMIFORM APPENDIX, NEGATIVE FOR TUMOR.
- SEE TEMPLATE.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Right hemicolectomy
Tumor Site:	Cecum
Tumor Configuration:	Exophytic (polypoid)
Tumor Size:	4.5 x 3.2 x 1.0 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	Moderately differentiated to poorly differentiated
Extent of Invasion:	Superficial muscularis propria
Margins:	Margins uninvolved by invasive carcinoma
Venous/Lymphatic Invasion:	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	Hyperplastic polyps
Extent of Resection:	R0: Complete resection with grossly and microscopically negative margins
Lymph Nodes:	Negative (0/16)
Implants:	Absent
Pathologic Stage:	pT2 N0 Mx

SPECIMEN(S):

A. TERMINAL ILEUM AND RIGHT COLON

CLINICAL HISTORY:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Colon and ileum, resection: Tumor at 9cm from proximal margin.

GROSS DESCRIPTION:

A. TERMINAL ILEUM RIGHT COLON

Received fresh labeled as "terminal ileum right colon" is a 28cm in length right colon and terminal ileum. The specimen is opened to reveal a tumor mass at the cecum measuring 4.5x3.2x1.0cm. The mass is sessile/ polypoid and raised. The mass is 1.5cm from the cecal valve and is 9 cm from the closest surgical resection margin. The serosa is inked blue corresponding to the lesion. The mass is sectioned and does not appear to go through the mucosa. There are two other tan polypoid lesions noted on the mucosal surface measuring 0.9 and 1.3 cm. in greatest dimension. There is an attached appendix measuring 10x1cm. The appendix is serially sectioned and reveals fecal material in the tip.

Representative sections are submitted in 12 cassettes as follows:

- A1-A2: margins
- A3-A5: tumor
- A6: 2 presumed polyps
- A7-A8: representative sections of normal bowel
- A9: appendix with the proximal portion notched
- A10: 7 lymph nodes
- A11: 6 lymph nodes in toto

[page 2 of 2]
[REDACTED]

A12: 3 lymph nodes in toto, 1 bisected lymph node
A13: representative section of ileocecal valve
A14-A16: other sections of tumor mass
90% of the tumor is submitted.

[REDACTED]

Source: NCI Genomic Data Commons file f1c1d9c1-a4a7-4763-83d9-bcfc00e791ce (TCGA-G4-6628.CCDB21AE-AB24-4AFE-84B6-123B716F5C12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).